Surgical pathology report (de-identified scan), TCGA case TCGA-CG-4474, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-4474-01A (Primary Tumor).

■
Diagnosis:

1. and 2.: Gastrectomy preparation with inclusion of a poorly differentiated adenocarcinoma or gastric carcinoma of diffuse type (so-called signet ring cell carcinoma) located in the antrum on the lesser curvature and extending to the aboral resection margin (duodenum) with penetration of the peritoneum, six regional lymph node metastases and also metastases both in the omentum (2.) and in the peritoneum (1.) (pT4a R1 pN2 (6/39) pM1 ■)

Source: NCI Genomic Data Commons file 5c256eaa-a6be-4a69-9e7e-063f49993d3c (TCGA-CG-4474.70B6D44B-AAB9-414F-8642-CFAB34F2EFA2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).